Somatic mutation profile of tumor specimen MP2PRT-PARVAN-TMP1-A (aliquot MP2PRT-PARVAN-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARVAN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.6 years (2,041 days).
Specimen MP2PRT-PARVAN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d7dc4c2-1ea3-4e81-a773-0177be877f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVAN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVAN-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4707b658-a1b2-45cf-bd39-5f712f0247ba

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 87/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518970, COSV62104015; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- RTL1 | c.1549G>A p.D517N | Missense Mutation (SNP) | VAF 100/419 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs759121692, COSV66016500; called by muse, mutect2, varscan2
- DPP6 | c.692G>T p.S231I (on ENST00000377770 / NM_001364500.2; = p.S169I on NM_001936.5) | Missense Mutation (SNP) | VAF 128/303 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PYGO1 | c.541G>C p.A181P | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- UBE2A | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.099); called by muse, mutect2
- UBE2A | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 85/354 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGB | c.2259C>T p.N753= | Silent (SNP) | VAF 114/264 reads (43%) | catalogued as rs773614365, COSV58857266; called by muse, mutect2, varscan2
- ALS2 | c.4740G>A p.E1580= | Silent (SNP) | VAF 84/357 reads (24%) | called by muse, mutect2, varscan2
- KBTBD7 | c.693G>A p.L231= | Silent (SNP) | VAF 66/373 reads (18%) | catalogued as rs1236109367; called by muse, mutect2, varscan2
- KIF4A | c.2904A>G p.E968= | Silent (SNP) | VAF 77/339 reads (23%) | called by muse, mutect2, varscan2
